Somatic mutation profile of tumor specimen TCGA-AQ-A54O-01A (aliquot TCGA-AQ-A54O-01A-11D-A25Q-09) from TCGA case TCGA-AQ-A54O, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.2 years (18,694 days).
Specimen TCGA-AQ-A54O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ea45abf-31f3-498f-b85f-bb3c0df6295c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A54O-10A (Blood Derived Normal), aliquot TCGA-AQ-A54O-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a71a684a-a522-4d47-a733-17c512651ca1

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS14 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs770167458, COSV64600378; called by muse, mutect2, varscan2
- ANP32A | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51189392; called by muse, mutect2, varscan2
- BAZ1A | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV62409416; called by muse, mutect2, varscan2
- CA2 | c.744G>T p.Q248H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53406060; called by muse, mutect2, varscan2
- CCDC61 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs768308257, COSV54427991; called by muse, mutect2, varscan2
- EML5 | c.2663G>A p.C888Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61342966; called by muse, mutect2, varscan2
- ERBB4 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1254584225, COSV53511860; called by muse, mutect2, varscan2
- FLRT2 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58137923; called by muse, mutect2, varscan2
- GALNT1 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV52451334; called by muse, mutect2, varscan2
- GBE1 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70097613; called by muse, mutect2, varscan2
- KLF11 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756956843, COSV59940151; called by muse, mutect2, varscan2
- MAML2 | c.2868G>A p.M956I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101594188, COSV73262952; called by muse, mutect2, varscan2
- ODF3L2 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59622763, COSV59623222; called by muse, mutect2, varscan2
- OS9 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.197); catalogued as COSV57782186; called by muse, mutect2, varscan2
- OXSM | c.560del p.M187Rfs*37 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as COSV55000911; called by mutect2, pindel, varscan2
- PCLO | c.8551G>A p.A2851T | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs1479815537, COSV61622174; called by muse, mutect2, varscan2
- KIF18A | c.705C>A p.Y235* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- LRBA | c.8487G>T p.L2829= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV63951435; called by muse, varscan2
- LRRTM1 | c.171C>T p.L57= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV54439193; called by muse, mutect2, varscan2
- OTUD7A | c.114G>A p.T38= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs772949592, COSV61036716; called by muse, mutect2, varscan2
- TOM1L2 | c.582G>A p.S194= (on ENST00000379504 / NM_001350333.2; = p.S144= on NM_001033551.3) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1335580426, COSV58884608; called by muse, mutect2, varscan2
